TCGA case TCGA-21-5784 — Lung Squamous Cell Carcinoma (TCGA-LUSC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung; Tissue source site: Fox Chase Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/4add88b7-169a-448f-b063-c7e6402628f1

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 80 years; Vital status: Alive.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; ICD-10 code: C34.1; Tissue or organ of origin: Upper lobe, lung; Site of resection or biopsy: Lung, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 80.4 years (29,362 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T2; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage IB; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 1,268 days (3.5 years); Sites of involvement: Central Lung.
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 908 days (2.5 years); Disease response: Tumor Free.
- Days to follow up: 1,268 days (3.5 years); Disease response: Tumor Free.

Other clinical attributes
- DLCO (% of predicted): 69; FEV1/FVC before bronchodilator (%): 74; FEV1 before bronchodilator (% of reference): 80.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 14; Tobacco smoking quit year: 1978.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-21-5784-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1; Intermediate dimension: 1; Shortest dimension: 0.4.
  Slide TCGA-21-5784-01A-01-BS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 50; Percent normal cells: 50; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 20; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 20.
  Slide TCGA-21-5784-01A-01-TS1: Section location: Top; Percent tumor cells: 62; Percent tumor nuclei: 68; Percent normal cells: 33; Percent necrosis: 5; Percent stromal cells: 0; Percent lymphocyte infiltration: 10; Percent monocyte infiltration: 5; Percent neutrophil infiltration: 10.
- Sample TCGA-21-5784-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-21-5784-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Submitted tumor site: Lung; Histologic diagnosis: Lung Squamous Cell Carcinoma- Not Otherwise Specified (NOS); History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Tobacco smoking history indicator: 3; Anatomic organ subdivision: R-Upper; Location lung parenchyma: Central Lung; Pulmonary function test indicator: Yes.
- Follow-up form 1: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome at TCGA followup: Complete Remission/Response.
- Follow-up form 2: Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No; Tumor status: Tumor free; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: No; Treatment outcome at TCGA followup: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,268 days; disease-specific survival: no event (censored), 1,268 days; disease-free interval: no event (censored), 1,268 days; progression-free interval: no event (censored), 1,268 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-21-5784-01A-01D-1631-01): tumor purity 0.18, ploidy 2.39, whole-genome doublings 1.
